Somatic mutation profile of tumor specimen TCGA-34-2608-01A (aliquot TCGA-34-2608-01A-02D-1522-08) from TCGA case TCGA-34-2608, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 84.8 years (30,958 days).
Specimen TCGA-34-2608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c410b1a-9b13-41ce-971a-553ededbf630.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2608-11A (Solid Tissue Normal), aliquot TCGA-34-2608-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9d73d5e-285d-4e6d-acb0-916f727fe2b7

The open-access MAF lists 154 somatic variants for this specimen: 108 protein-altering or splice-affecting, 40 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 40, Nonsense Mutation 9, Intron 3, Splice Site 3, RNA 3, Splice Region 2, In Frame Del 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMER2 | c.1700C>A p.A567E | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV63436269; called by muse, mutect2
- AMY2B | c.315G>T p.G105= | Splice Region (SNP) | VAF 28/298 reads (9%) | catalogued as rs1189364425, COSV63714093; called by muse, mutect2
- ATMIN | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55145202; called by muse, mutect2, varscan2
- ATP2B4 | c.2983A>G p.I995V | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs940319491, COSV58174490; called by muse, mutect2, varscan2
- CAST | c.1037A>G p.D346G (on ENST00000341926; = p.D429G on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57782334; called by muse, mutect2, varscan2
- CCND1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV57119390; called by muse, mutect2, varscan2
- CDH8 | c.835+1G>A p.X279_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | catalogued as COSV54849909, COSV54895721; called by muse, mutect2
- CLEC9A | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV59531004; called by muse, mutect2
- CLSTN3 | c.2434C>G p.H812D | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56934151; called by muse, mutect2, varscan2
- COL12A1 | c.8911C>G p.P2971A | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV59389937; called by muse, mutect2, varscan2
- CPAMD8 | c.463C>T p.Q155* (on ENST00000651564; = p.Q108* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99359033; called by muse, mutect2, varscan2
- CSMD1 | c.9353C>A p.S3118Y (on ENST00000520002; = p.S3117Y on NM_033225.6) | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.354); catalogued as COSV59284313; called by muse, mutect2
- CSMD3 | c.3403C>A p.R1135S (on ENST00000297405 / NM_001363185.1; = p.R1031S on NM_052900.3) | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52108004; called by muse, mutect2, varscan2
- CTCFL | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 34/201 reads (17%) | catalogued as rs764892808, COSV54771065; called by muse, mutect2, varscan2
- CTNNA3 | c.1465C>G p.H489D | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV65551521, COSV65555140, COSV65598974; called by muse, mutect2, varscan2
- CYP4F8 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV57853172; called by muse, mutect2, varscan2
- DCC | c.440A>T p.E147V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.374); catalogued as COSV59085867; called by muse, mutect2
- DCN | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV50006111; called by muse, mutect2
- DHX8 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 15/140 reads (11%) | catalogued as rs751521418, COSV52251003; called by muse, mutect2, varscan2
- DNAH7 | c.9291+1G>A p.X3097_splice | Splice Site (SNP) | VAF 20/176 reads (11%) | catalogued as COSV56752932; called by muse, mutect2
- DPPA4 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 36/283 reads (13%) | catalogued as COSV59509371; called by muse, mutect2, varscan2
- ENOX1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54888166, COSV99816728; called by muse, mutect2
- F13A1 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53553754; called by muse, mutect2
- F13A1 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53553764; called by muse, mutect2
- F5 | c.359G>C p.S120T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV63120907; called by muse, mutect2, varscan2
- FADS6 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372010502; called by muse, mutect2, varscan2
- FAT3 | c.12268C>A p.L4090I | Missense Mutation (SNP) | VAF 65/480 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV53078757; called by muse, mutect2, varscan2
- FBXO30 | c.914G>A p.G305D | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52790258; called by muse, mutect2
- FSHR | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.335); catalogued as COSV58617975; called by muse, mutect2
- GALP | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV61999236; called by muse, mutect2
- GLI2 | c.3945G>A p.M1315I (on ENST00000361492 / NM_001374353.1; = p.M1332I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as COSV100082530; called by muse, varscan2
- GPR158 | c.3242T>C p.I1081T | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV66265731; called by muse, mutect2, varscan2
- GRB10 | c.1641C>T p.C547= (on ENST00000398812; = p.C501= on NM_001001549.3) | Splice Region (SNP) | VAF 14/125 reads (11%) | catalogued as rs375434973; called by muse, mutect2, varscan2
- HERC5 | c.2683G>C p.D895H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV52037403; called by muse, mutect2
- HTR1A | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60499942, COSV60500518; called by muse, mutect2, varscan2
- INPP4B | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53711924; called by muse, mutect2, varscan2
- IQGAP3 | c.4740G>T p.K1580N | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV63249536; called by muse, mutect2
- KDM5C | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64762900; called by muse, mutect2, varscan2
- KIF1B | c.5180G>T p.R1727L (on ENST00000377086 / NM_001365952.1; = p.R1681L on NM_015074.3) | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55803801; called by muse, mutect2
- KLF15 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs983434622, COSV56179511; called by muse, mutect2
- KRT28 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV60683692; called by muse, mutect2, varscan2
- LGSN | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV65726294; called by muse, mutect2, varscan2
- LIG3 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV52005943; called by muse, mutect2, varscan2
- LRP2 | c.8225C>A p.S2742* | Nonsense Mutation (SNP) | VAF 13/137 reads (9%) | catalogued as COSV55541741; called by muse, mutect2, varscan2
- MICALL2 | c.2037G>T p.W679C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52514142; called by muse, mutect2, varscan2
- MMD2 | c.782C>T p.P261L (on ENST00000404774 / NM_001100600.2; = p.P237L on NM_198403.4) | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV68659764; called by muse, mutect2, varscan2
- MXRA8 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV58509884; called by muse, mutect2
- MYH15 | c.3640G>C p.E1214Q | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56304697; called by muse, mutect2, varscan2
- MYL1 | c.297C>A p.S99R | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV58974200; called by muse, mutect2
- NBAS | c.4320G>T p.K1440N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV55713253; called by muse, mutect2, varscan2
- NELL2 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV61569541; called by muse, mutect2, varscan2
- NOX3 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763222728, COSV50148772; called by muse, mutect2
- NPAS4 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60648942; called by muse, mutect2, varscan2
- NPHP4 | c.1020A>T p.R340S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV65393264; called by muse, mutect2, varscan2
- NR1H3 | c.1344A>T p.*448Cext*27 | Nonstop Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV60620694; called by muse, mutect2
- OR10Q1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs778216887, COSV57469754; called by muse, mutect2
- OR2M4 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100141494, COSV60707288; called by muse, mutect2, varscan2
- OR4C16 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs150706012, COSV58940789; called by muse, mutect2, varscan2
- PCDH10 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV52087894; called by muse, mutect2, varscan2
- PCDH11X | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100008984; called by mutect2, varscan2
- PCDHA1 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.067); catalogued as COSV65372753; called by muse, mutect2
- PCDHB6 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV99169949; called by muse, varscan2
- PEAR1 | c.229C>A p.R77S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52770905, COSV52771881; called by muse, mutect2
- PEX12 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs988442642, COSV56777592; called by muse, mutect2
- PIGQ | c.1532-1G>T p.X511_splice (on ENST00000026218 / NM_148920.3; = p.X532_splice on NM_004204.5) | Splice Site (SNP) | VAF 40/324 reads (12%) | catalogued as COSV50312246; called by muse, mutect2, varscan2
- PKHD1 | c.375T>G p.D125E | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.056); catalogued as rs749231751, COSV61861712; called by muse, mutect2
- PPP1R3C | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV53287670; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- RAB6B | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53312195; called by muse, mutect2, varscan2
- RDH10 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53581343; called by muse, mutect2
- ROPN1L | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.821); catalogued as rs748897594, COSV56873037, COSV56873920; called by muse, mutect2, varscan2
- RP1 | c.2303C>G p.S768C | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs1162608680, COSV55110595, COSV55111673; called by muse, mutect2
- RPP25L | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52406383; called by muse, mutect2, varscan2
- RYR3 | c.6406C>A p.P2136T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66778813; called by muse, mutect2, varscan2
- SACM1L | c.1598C>T p.S533L | Missense Mutation (SNP) | VAF 50/418 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV66612485; called by muse, mutect2, varscan2
- SCN7A | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 29/276 reads (11%) | catalogued as COSV69268752; called by muse, mutect2
- SERPINB5 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV101237614; called by muse, mutect2, varscan2
- SERTM1 | c.233A>T p.E78V | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV59375736; called by muse, mutect2
- SLC12A6 | c.2442A>G p.I814M (on ENST00000354181 / NM_001365088.1; = p.I763M on NM_005135.2) | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.211); catalogued as COSV51623036; called by muse, mutect2, varscan2
- SLC39A2 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751140614, COSV53868929; called by muse, mutect2, varscan2
- SMPD1 | c.601A>G p.S201G | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.211); catalogued as COSV54966491; called by muse, mutect2
- SSH2 | c.2443G>C p.E815Q | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV52166891, COSV52182746; called by muse, mutect2, varscan2
- STON1 | c.1217C>A p.P406Q | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.063); catalogued as COSV59126478; called by muse, mutect2, varscan2
- TCHHL1 | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 57/374 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1260388944, COSV64284920; called by muse, mutect2, varscan2
- TENT4B | c.1560T>A p.D520E (on ENST00000561678 / NM_001365323.2; = p.D505E on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.033); catalogued as COSV62546388; called by muse, mutect2, varscan2
- TLN2 | c.4422G>T p.Q1474H | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60885827; called by muse, mutect2, varscan2
- TMC3 | c.1467C>A p.S489R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1486775230, COSV63922243; called by muse, mutect2, varscan2
- TMEM131 | c.3577A>T p.S1193C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV51770444; called by muse, mutect2
- TOM1 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65897416; called by muse, mutect2
- TRIP12 | c.1838A>G p.H613R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV52259526; called by muse, mutect2, varscan2
- TTN | c.81059T>C p.V27020A (on ENST00000591111; = p.V19596A on NM_003319.4) | Missense Mutation (SNP) | VAF 22/220 reads (10%) | PolyPhen benign (0.082); catalogued as COSV59899643; called by muse, mutect2, varscan2
- TTN | c.10658T>C p.F3553S (on ENST00000591111; = p.F3507S on NM_003319.4) | Missense Mutation (SNP) | VAF 31/218 reads (14%) | catalogued as COSV59899681; called by muse, mutect2, varscan2
- UBE3B | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV55091427; called by muse, mutect2, varscan2
- UMODL1 | c.1076A>T p.Q359L | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61159357; called by muse, mutect2
- WDR1 | c.1345G>T p.E449* (on ENST00000382452; = p.E309* on NM_005112.5) | Nonsense Mutation (SNP) | VAF 8/113 reads (7%) | catalogued as COSV66723307, COSV66726883; called by muse, mutect2
- WDR72 | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as COSV100854286, COSV64741937; called by muse, mutect2
- XDH | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65147019, COSV65147868; called by muse, mutect2, varscan2
- ZBTB43 | c.609T>G p.H203Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV65094415; called by muse, mutect2, varscan2
- ZFP42 | c.225C>A p.C75* | Nonsense Mutation (SNP) | VAF 11/133 reads (8%) | catalogued as rs369075421, COSV58816454; called by muse, mutect2
- ZFP91 | c.1135C>G p.R379G | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60157005; called by muse, mutect2
- ZNF181 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV67626319; called by muse, mutect2
- ZNF341 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV61006068; called by muse, mutect2, varscan2
- ZNF493 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV62749188; called by muse, mutect2
- ZNF676 | c.107A>T p.N36I (on ENST00000650058; = p.N4I on NM_001001411.3) | Missense Mutation (SNP) | VAF 53/420 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV68092241; called by muse, mutect2, varscan2
- ZNF831 | c.4607A>C p.E1536A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV64037653; called by muse, mutect2, varscan2
- H3C2 | c.191_196del p.R64_K65del | In Frame Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel*
- TRIP11 | c.5421del p.S1808Afs*25 | Frame Shift Del (DEL) | VAF 29/210 reads (14%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.2187C>T p.I729= | Silent (SNP) | VAF 36/490 reads (7%) | catalogued as COSV51560435; called by muse, mutect2
- ALKBH4 | c.327T>C p.Y109= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1443631727, COSV52960397; called by muse, mutect2
- ANKS3 | c.1860C>T p.L620= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as rs1450948635, COSV58507307; called by muse, mutect2, varscan2
- APOA5 | c.591C>T p.S197= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1277126015, COSV57062354; called by muse, mutect2
- ARF5 | c.408G>T p.V136= | Silent (SNP) | VAF 33/283 reads (12%) | catalogued as COSV50000309; called by muse, mutect2, varscan2
- ARHGEF38 | c.336T>C p.D112= | Silent (SNP) | VAF 29/233 reads (12%) | catalogued as rs146153509; called by muse, mutect2, varscan2
- C1orf174 | c.657C>T p.S219= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV59495816; called by muse, mutect2, varscan2
- CALD1 | c.304C>A p.R102= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV62645239; called by muse, mutect2, varscan2
- CDC42BPG | c.705G>A p.P235= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as rs149531322; called by muse, mutect2
- CSGALNACT1 | c.798C>T p.I266= | Silent (SNP) | VAF 98/826 reads (12%) | catalogued as rs1340498278, COSV59974085; called by muse, mutect2, varscan2
- DDN | c.1284G>A p.E428= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as COSV60291588; called by muse, mutect2, varscan2
- DDX60L | c.4320C>T p.L1440= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV52708906, COSV99487935; called by muse, mutect2
- EPHA5 | c.1782C>T p.L594= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs1489893828, COSV56632328; called by muse, mutect2, varscan2
- EXD3 | c.1761C>T p.H587= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV59803789; called by mutect2, varscan2
- FNDC7 | c.711C>T p.S237= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs747899150, COSV54750931; called by muse, mutect2, varscan2
- FUT8 | c.9A>G p.P3= | Silent (SNP) | VAF 36/302 reads (12%) | catalogued as COSV61280374; called by muse, mutect2, varscan2
- GPR45 | c.777G>A p.L259= | Silent (SNP) | VAF 48/342 reads (14%) | catalogued as COSV51522812; called by muse, mutect2, varscan2
- GRIK3 | c.2271G>T p.G757= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV66135900; called by muse, mutect2
- HYAL3 | c.102G>A p.L34= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV56496841; called by muse, mutect2, varscan2
- IL1R2 | c.225T>C p.A75= | Silent (SNP) | VAF 59/466 reads (13%) | catalogued as COSV60205762; called by muse, mutect2, varscan2
- IL3RA | c.150C>T p.I50= | Silent (SNP) | VAF 22/394 reads (6%) | catalogued as rs751664291, COSV58429960; called by muse, mutect2
- IREB2 | c.2223T>C p.H741= | Silent (SNP) | VAF 72/453 reads (16%) | catalogued as rs1041096900, COSV51920773; called by muse, mutect2, varscan2
- KCNG1 | c.492C>T p.C164= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV65367981; called by muse, mutect2, varscan2
- KCNH8 | c.267G>A p.E89= | Silent (SNP) | VAF 27/268 reads (10%) | catalogued as COSV60457133, COSV60470172; called by muse, mutect2
- KIF26A | c.2784C>T p.S928= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs776386864, COSV59464645; called by muse, mutect2, varscan2
- OR1L4 | c.120G>A p.A40= | Silent (SNP) | VAF 14/262 reads (5%) | catalogued as rs1180879323, COSV52339752; called by muse, mutect2
- PYGM | c.2091T>C p.N697= | Silent (SNP) | VAF 42/294 reads (14%) | catalogued as COSV51214920; called by muse, mutect2, varscan2
- RCN1 | c.384T>C p.D128= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV50014286; called by muse, mutect2, varscan2
- RPL26L1 | c.318C>T p.I106= | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as COSV54199159; called by muse, mutect2, varscan2
- RUNX2 | c.984G>A p.G328= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as rs1209757399, COSV61838940, COSV61843145; called by muse, mutect2
- SHC2 | c.1233G>A p.E411= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV52743906; called by muse, mutect2, varscan2
- SLC5A8 | c.225C>A p.P75= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV73310379; called by muse, mutect2
- STAG1 | c.759C>T p.A253= | Silent (SNP) | VAF 19/310 reads (6%) | catalogued as rs113504457; called by muse, mutect2
- STK35 | c.1491C>A p.S497= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV55689588; called by muse, mutect2, varscan2
- TAP1 | c.330C>T p.T110= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs746167727; called by muse, mutect2
- TBX21 | c.1377C>A p.G459= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV51595117; called by muse, mutect2, varscan2
- TMC2 | c.2349C>G p.S783= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV62649963; called by muse, mutect2, varscan2
- TRPC5 | c.1884T>C p.Y628= | Silent (SNP) | VAF 76/285 reads (27%) | catalogued as COSV53284736; called by muse, mutect2, varscan2
- UMODL1 | c.1191C>T p.A397= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs1459809830, COSV61159362; called by muse, mutect2
- ZBTB21 | c.1902C>A p.A634= | Silent (SNP) | VAF 13/199 reads (7%) | catalogued as COSV60403222; called by muse, mutect2
- ATP2B1 | c.3351+409C>T | Intron (SNP) | VAF 68/506 reads (13%) | catalogued as COSV99665266; called by muse, varscan2
- MIR518E | n.21G>T | RNA (SNP) | VAF 25/263 reads (10%) | called by muse, mutect2
- MIR668 | n.56G>A | RNA (SNP) | VAF 12/142 reads (8%) | catalogued as rs776614527; called by muse, mutect2
- NALCN | c.1765-4939T>A | Intron (SNP) | VAF 10/125 reads (8%) | catalogued as COSV99213348; called by muse, mutect2
- RPL31P57 | n.60G>C | RNA (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- TTN | c.10303+2241C>T | Intron (SNP) | VAF 19/155 reads (12%) | catalogued as COSV59899704; called by muse, mutect2, varscan2
